Somatic mutation profile of tumor specimen C3N-02002-02 (aliquot CPT0109720010) from CPTAC case C3N-02002, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 76.4 years (27,900 days).
Specimen C3N-02002-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1506fa2a-0a06-4126-8c64-49ea716261bc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02002-71 (Blood Derived Normal), aliquot CPT0139130002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/33afd0d9-6140-49f2-a8ce-29d40a92825c

The open-access MAF lists 74 somatic variants for this specimen: 44 protein-altering or splice-affecting, 19 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 19, Intron 5, Frame Shift Ins 3, 3'UTR 3, 5'UTR 2, Splice Region 2, Splice Site 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 144/449 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- ALDH18A1 | c.140C>T p.P47L | Missense Mutation (SNP) | VAF 10/324 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1258297586; called by muse, mutect2
- CD163L1 | c.1258C>T p.R420C | Missense Mutation (SNP) | VAF 27/240 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.823); catalogued as rs779416105, COSV58016469; called by muse, mutect2, varscan2
- CMYA5 | c.7820C>G p.P2607R | Missense Mutation (SNP) | VAF 69/331 reads (21%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.859); catalogued as rs375923511; called by muse, mutect2, varscan2
- GREB1 | c.1453C>T p.P485S | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0.085); catalogued as rs779035515; called by muse, mutect2
- ITGA3 | c.3048C>T p.C1016= | Splice Region (SNP) | VAF 9/107 reads (8%) | catalogued as rs775983973; called by muse, mutect2
- MAGEB6B | c.670C>T p.R224C | Missense Mutation (SNP) | VAF 88/128 reads (69%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs751620886; called by muse, mutect2, varscan2
- NCAPG2 | c.25C>A p.Q9K | Missense Mutation (SNP) | VAF 30/174 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.077); catalogued as rs77960215; called by muse, mutect2, varscan2
- OPLAH | c.2438del p.P813Lfs*6 | Frame Shift Del (DEL) | VAF 34/109 reads (31%) | catalogued as COSV70678018; called by mutect2, pindel, varscan2
- PDHX | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 27/270 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs72912954; ClinVar: uncertain significance; called by muse, mutect2
- SCD5 | c.724G>C p.A242P | Missense Mutation (SNP) | VAF 45/256 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60298454; called by muse, mutect2, varscan2
- SIGLEC12 | c.1106C>T p.T369I (on ENST00000291707 / NM_053003.4; = p.T251I on NM_033329.2) | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.886); catalogued as rs915853103; called by muse, mutect2, varscan2
- SLC49A4 | c.408A>G p.I136M | Missense Mutation (SNP) | VAF 8/192 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs1301480298; called by muse, mutect2
- SMYD1 | c.272C>T p.S91L | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs371262032; called by muse, mutect2, varscan2
- SPR | c.739A>G p.K247E | Missense Mutation (SNP) | VAF 11/273 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1183021154; called by muse, mutect2
- TMPRSS6 | c.79A>T p.M27L | Missense Mutation (SNP) | VAF 38/396 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs763912943; called by muse, mutect2
- TUBGCP5 | c.10C>T p.H4Y | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0.011); catalogued as rs755112473; called by muse, mutect2
- ZNF300 | c.1676C>G p.S559C | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.178); catalogued as COSV51053588; called by muse, mutect2, varscan2
- ALDH1L1 | c.1076+2T>G p.X359_splice | Splice Site (SNP) | VAF 22/119 reads (18%) | called by muse, mutect2, varscan2
- BAHD1 | c.161A>G p.N54S | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.64); PolyPhen benign (0.025); called by muse, mutect2
- CDH6 | c.748G>A p.G250R | Missense Mutation (SNP) | VAF 34/211 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- COPS8 | c.330A>C p.R110S | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.069); called by muse, varscan2
- CREBBP | c.2089C>G p.Q697E | Missense Mutation (SNP) | VAF 72/210 reads (34%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- CSMD2 | c.7328C>T p.S2443F | Missense Mutation (SNP) | VAF 18/283 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.637); called by muse, mutect2
- DENND4B | c.3883T>G p.S1295A | Missense Mutation (SNP) | VAF 12/306 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2
- MAP3K7 | c.1770dup p.Q591Tfs*41 (on ENST00000369329 / NM_145331.3; = p.Q564Tfs*41 on NM_003188.4) | Frame Shift Ins (INS) | VAF 64/278 reads (23%) | called by mutect2, pindel, varscan2
- MROH1 | c.4271C>G p.A1424G | Missense Mutation (SNP) | VAF 14/408 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2
- MYO9A | c.5829T>G p.D1943E | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.4); called by muse, mutect2, varscan2
- MYORG | c.551A>C p.H184P | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- NAGPA | c.791+5G>T | Splice Region (SNP) | VAF 49/360 reads (14%) | called by muse, mutect2, varscan2
- NOTCH4 | c.5195A>C p.K1732T | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- PARD6B | c.582A>G p.I194M | Missense Mutation (SNP) | VAF 17/306 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PROSER2 | c.536C>T p.S179F | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.773); called by muse, mutect2
- PRRG4 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 41/159 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTPN13 | c.3031G>A p.D1011N | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- RUNDC1 | c.434A>T p.D145V | Missense Mutation (SNP) | VAF 11/210 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.058); called by muse, mutect2
- SEC16A | c.6956dup p.P2321Sfs*75 | Frame Shift Ins (INS) | VAF 30/212 reads (14%) | called by mutect2, pindel
- SPZ1 | c.823C>A p.Q275K | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); called by muse, mutect2
- TENT2 | c.56A>C p.H19P | Missense Mutation (SNP) | VAF 55/144 reads (38%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- TFAP2D | c.1111G>A p.D371N | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.055); called by muse, mutect2
- TRPC4AP | c.520T>G p.C174G | Missense Mutation (SNP) | VAF 15/186 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.446); called by muse, mutect2
- USP36 | c.2287T>G p.S763A | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- VCAN | c.7298C>A p.S2433Y | Missense Mutation (SNP) | VAF 28/493 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF92 | c.488dup p.N163Kfs*2 (on ENST00000328747 / NM_152626.4; = p.N94Kfs*2 on NM_007139.4) | Frame Shift Ins (INS) | VAF 14/49 reads (29%) | called by mutect2, pindel, varscan2
- ARFGEF3 | c.912A>T p.G304= | Silent (SNP) | VAF 7/167 reads (4%) | called by muse, mutect2
- BAG5 | c.1053C>T p.A351= | Silent (SNP) | VAF 17/355 reads (5%) | called by muse, mutect2
- CYP24A1 | c.414C>A p.R138= | Silent (SNP) | VAF 65/272 reads (24%) | called by muse, mutect2, varscan2
- EFS | c.1362G>T p.V454= | Silent (SNP) | VAF 7/49 reads (14%) | called by muse, mutect2, varscan2
- FCN2 | c.465C>T p.F155= | Silent (SNP) | VAF 128/291 reads (44%) | catalogued as rs867095740; called by muse, varscan2
- HSD3B2 | c.1080G>T p.V360= | Silent (SNP) | VAF 79/201 reads (39%) | catalogued as rs752508551; called by muse, mutect2, varscan2
- KCNN4 | c.1194G>A p.T398= | Silent (SNP) | VAF 40/206 reads (19%) | catalogued as rs141571998; called by muse, mutect2, varscan2
- OR5AK2 | c.213C>A p.I71= | Silent (SNP) | VAF 11/99 reads (11%) | catalogued as COSV58805325; called by muse, mutect2, varscan2
- PCDHA12 | c.87C>A p.G29= | Silent (SNP) | VAF 96/260 reads (37%) | catalogued as rs1554167755; called by muse, mutect2, varscan2
- PCNX3 | c.3159G>A p.L1053= | Silent (SNP) | VAF 34/178 reads (19%) | catalogued as rs1424248816; called by muse, mutect2, varscan2
- RAB11FIP4 | c.1123C>T p.L375= | Silent (SNP) | VAF 8/177 reads (5%) | called by muse, mutect2
- RGS4 | c.222A>G p.A74= | Silent (SNP) | VAF 19/67 reads (28%) | called by mutect2, varscan2
- RIPK4 | c.444C>T p.N148= | Silent (SNP) | VAF 10/114 reads (9%) | called by muse, mutect2
- RNPEP | c.372G>A p.V124= | Silent (SNP) | VAF 10/164 reads (6%) | called by muse, mutect2
- TBL3 | c.357C>T p.P119= | Silent (SNP) | VAF 24/75 reads (32%) | catalogued as rs759295340; called by muse, mutect2, varscan2
- TRIM28 | c.1383A>G p.A461= | Silent (SNP) | VAF 24/292 reads (8%) | called by muse, mutect2
- U2AF1L4 | c.420G>T p.V140= (on ENST00000412391; = p.V101= on NM_144987.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/180 reads (12%) | called by muse, mutect2, varscan2
- UBFD1 | c.615T>C p.S205= | Silent (SNP) | VAF 37/128 reads (29%) | called by muse, mutect2, varscan2
- ZNF146 | c.516A>T p.I172= | Silent (SNP) | VAF 33/141 reads (23%) | catalogued as COSV61932666; called by muse, mutect2, varscan2
- ADGRE3 | c.393+11G>C | Intron (SNP) | VAF 9/133 reads (7%) | called by muse, mutect2
- AL583810.2 | n.354G>A | RNA (SNP) | VAF 8/192 reads (4%) | catalogued as rs955952891; called by muse, mutect2
- ALYREF | c.-2C>T | 5'UTR (SNP) | VAF 14/162 reads (9%) | catalogued as rs1052702910; called by muse, mutect2
- ARPP21 | c.2032+591T>C | Intron (SNP) | VAF 9/51 reads (18%) | called by muse, mutect2, varscan2
- DIP2C | c.85+39248C>T | Intron (SNP) | VAF 48/165 reads (29%) | called by muse, mutect2, varscan2
- DIP2C | c.85+38140C>T | Intron (SNP) | VAF 64/251 reads (25%) | called by muse, mutect2, varscan2
- GPATCH8 | c.*2007C>A | 3'UTR (SNP) | VAF 89/298 reads (30%) | called by muse, mutect2, varscan2
- PRUNE1 | c.-35_-11del | 5'UTR (DEL) | VAF 35/408 reads (9%) | called by mutect2, pindel
- RPL7L1 | c.147+27A>T | Intron (SNP) | VAF 18/212 reads (8%) | called by muse, mutect2
- SERPINA7 | c.*29C>A | 3'UTR (SNP) | VAF 75/138 reads (54%) | called by muse, mutect2, varscan2
- SLC6A2 | c.*48C>T | 3'UTR (SNP) | VAF 8/181 reads (4%) | called by muse, mutect2
